Somatic mutation profile of tumor specimen TCGA-AA-3509-01A (aliquot TCGA-AA-3509-01A-01D-1408-10) from TCGA case TCGA-AA-3509, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage II; Age at diagnosis: 54.2 years (19,786 days).
Specimen TCGA-AA-3509-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cdf9224-1229-41c6-8a0e-1531b462a7fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3509-11A (Solid Tissue Normal), aliquot TCGA-AA-3509-11A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/217d2725-8235-4a1e-89da-6ab21d24962c

The open-access MAF lists 97 somatic variants for this specimen: 71 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 24, Nonsense Mutation 6, Frame Shift Del 2, In Frame Del 2, Splice Region 1, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3880C>T p.Q1294* | Nonsense Mutation (SNP) | VAF 73/96 reads (76%) | hotspot (GDC flag); catalogued as rs1554085373, CD058148, CD132712, CM930027, COSV57323524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 68/121 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- WFS1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs145639028, CM011516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.3266T>C p.I1089T (on ENST00000506720 / NM_001322402.2; = p.I1021T on NM_015236.6) | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV72231289; called by muse, mutect2
- AHNAK | c.4106C>G p.P1369R | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99949000; called by muse, mutect2, varscan2
- ANO10 | c.1800C>T p.H600= | Splice Region (SNP) | VAF 18/66 reads (27%) | catalogued as rs754900776; called by muse, mutect2, varscan2
- ASPHD1 | c.722G>A p.W241* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as rs778227912, COSV58101452; called by muse, mutect2, varscan2
- BPIFB1 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as rs551400282, COSV53608711; called by muse, mutect2, varscan2
- C2orf16 | c.4700G>A p.R1567H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs746926439, COSV62677071; called by muse, mutect2, varscan2
- CAND2 | c.1466G>A p.R489H (on ENST00000456430 / NM_001162499.2; = p.R396H on NM_012298.3) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1375841662; called by muse, mutect2, varscan2
- CCK | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 37/64 reads (58%) | catalogued as rs778151078, COSV58183411, COSV58183755; called by muse, mutect2, varscan2
- CNKSR2 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV99670068; called by muse, mutect2, varscan2
- CTNNA2 | c.1756G>T p.A586S | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as COSV58165297; called by muse, mutect2, varscan2
- ESPL1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99228802; called by muse, mutect2, varscan2
- GZMA | c.216G>T p.L72F | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.614); catalogued as COSV57113234; called by muse, mutect2, varscan2
- HCFC1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1557117889, COSV60075054; called by muse, mutect2, varscan2
- HMCN1 | c.14972G>A p.S4991N | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV54886240; called by muse, mutect2, varscan2
- HSPA14 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs769277323, COSV65684170; called by muse, mutect2, varscan2
- IL13RA2 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs1556509385, COSV54564971; called by muse, mutect2, varscan2
- INKA1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58526570; called by muse, mutect2, varscan2
- IRAK4 | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV71210523, COSV71210697; called by muse, mutect2, varscan2
- KIF1B | c.3245G>A p.R1082Q (on ENST00000377086 / NM_001365952.1; = p.R1036Q on NM_015074.3) | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs745363423, COSV55803809; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC7 | c.128G>A p.R43Q (on ENST00000651989 / NM_001370785.2; = p.R10Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747077838, COSV50418241, COSV99230272; called by muse, mutect2, varscan2
- LRRC8E | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs778982100; called by muse, mutect2, varscan2
- LTBP1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs370933815; called by muse, mutect2, varscan2
- MEFV | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs766608226, COSV99561007; called by muse, mutect2, varscan2
- MLH3 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV53135824; called by muse, mutect2, varscan2
- MYO5A | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs1219700349; called by muse, mutect2, varscan2
- NFATC4 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1459207514; called by muse, mutect2, varscan2
- NPAP1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs781365767, COSV61506293; called by muse, mutect2, varscan2
- NRXN1 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs201873057, COSV58440302, COSV58473195; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.469A>T p.T157S (on ENST00000259318 / NM_001136562.3; = p.T388S on NM_007203.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.138); catalogued as rs1239878693; called by muse, mutect2, varscan2
- PCBP4 | c.691G>A p.V231M (on ENST00000322099 / NM_033010.2; = p.V188M on NM_020418.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs773787182, COSV59056164; called by muse, mutect2, varscan2
- PIK3R5 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs370012186; called by muse, mutect2, varscan2
- PNMA8A | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV58138121; called by muse, mutect2, varscan2
- PRKCD | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1178121978, COSV100387806, COSV57848569; called by muse, mutect2, varscan2
- PSME4 | c.3536G>A p.R1179Q | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs762742024; called by muse, varscan2
- RBM33 | c.3281A>G p.K1094R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.994); catalogued as COSV62032259; called by muse, mutect2, varscan2
- RIC3 | c.959C>T p.A320V (on ENST00000309737 / NM_001206671.4; = p.A319V on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as rs754549385, COSV58303330; called by muse, mutect2, varscan2
- SAMD3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs772791075, COSV63717200, COSV63718675; called by muse, mutect2, varscan2
- SARDH | c.2602G>A p.G868S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1183015085, COSV64100698; called by muse, mutect2, varscan2
- SOX6 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100322135; called by muse, mutect2, varscan2
- TAF4 | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as rs752635209; called by muse, mutect2
- TCF7L2 | c.1219C>T p.R407* (on ENST00000355995 / NM_001367943.1; = p.R384* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV53338146; called by muse, mutect2, varscan2
- TEX264 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs745803321, COSV58136273; called by muse, mutect2, varscan2
- TMPRSS11D | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.34); catalogued as rs961924298; called by muse, mutect2, varscan2
- TPP2 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs753682674; called by muse, mutect2, varscan2
- TTLL2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs374723694; called by muse, mutect2, varscan2
- ZFR2 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.127); catalogued as rs185400185, COSV53599530, COSV53604876; called by muse, mutect2, varscan2
- ZNF205 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770380526, COSV54620873; called by muse, mutect2, varscan2
- ZSCAN18 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1245690645, COSV53731076; called by muse, mutect2, varscan2
- ADGRV1 | c.18244G>T p.A6082S | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID4A | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- ATP10A | c.3818T>G p.V1273G | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BLM | c.3875-1G>A p.X1292_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- CNKSR2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FERMT2 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY1A2 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR2C | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NOL9 | c.731T>G p.I244S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- NR5A2 | c.257_258del p.C86Sfs*6 (on ENST00000367362 / NM_205860.3; = p.C40Sfs*6 on NM_003822.5) | Frame Shift Del (DEL) | VAF 63/143 reads (44%) | called by mutect2, pindel, varscan2
- PKP4 | c.1372A>G p.S458G | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- PPWD1 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SMC4 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- STK32A | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SUPT16H | c.1423_1425del p.R475del | In Frame Del (DEL) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- TNFRSF11B | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- TYW5 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- URI1 | c.930_950del p.D311_D317del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by muse*, mutect2, varscan2*
- XKR9 | c.922T>C p.C308R | Missense Mutation (SNP) | VAF 77/300 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ZFP36L2 | c.602_605del p.H201Pfs*259 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- ADAMTS12 | c.159C>T p.H53= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs780048038, COSV100710421; called by muse, mutect2, varscan2
- ATP9A | c.1908C>T p.I636= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs762953435; called by mutect2, varscan2
- BEST1 | c.1053C>T p.S351= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs939414505; called by muse, mutect2, varscan2
- CABS1 | c.1140G>A p.T380= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs372887159, COSV99908933; called by muse, mutect2, varscan2
- CRTAC1 | c.315C>T p.Y105= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs571436527, COSV53998564; called by muse, mutect2, varscan2
- DCAF12L2 | c.843C>T p.S281= | Silent (SNP) | VAF 24/92 reads (26%) | called by muse, mutect2, varscan2
- DNAH3 | c.9294G>A p.A3098= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs199799884, COSV54516041, COSV54523440; called by muse, mutect2, varscan2
- FBXL7 | c.1095C>T p.D365= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs377071413; called by muse, mutect2, varscan2
- MAMLD1 | c.2112G>A p.P704= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs186596666, COSV99475507; called by muse, mutect2, varscan2
- MYO18B | c.6807G>A p.T2269= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs752396542; called by muse, mutect2, varscan2
- OR51B2 | c.423G>A p.A141= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs267602944; called by muse, mutect2, varscan2
- OR7A17 | c.88C>T p.L30= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV59414734; called by muse, mutect2, varscan2
- PAMR1 | c.159C>T p.C53= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs1162976422, COSV53512371; called by muse, mutect2, varscan2
- PLEKHH1 | c.1779G>A p.K593= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs774777716; called by muse, mutect2, varscan2
- RAPSN | c.336G>T p.L112= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs747080013; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC51A | c.678C>T p.G226= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs756068315; called by muse, mutect2, varscan2
- SLCO1B1 | c.522G>A p.V174= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as rs761806682; called by muse, mutect2, varscan2
- SPTBN5 | c.477G>A p.Q159= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- TIMM22 | c.513C>G p.G171= | Silent (SNP) | VAF 78/107 reads (73%) | called by muse, mutect2, varscan2
- TLN2 | c.6762C>T p.H2254= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs140658126; called by muse, mutect2, varscan2
- TRAPPC9 | c.264G>A p.S88= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as rs554862576; called by muse, mutect2
- TTC31 | c.1363A>C p.R455= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- UNC13C | c.504C>T p.D168= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs201832839; called by muse, mutect2, varscan2
- WDR13 | c.1167C>T p.N389= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs143153713, COSV54332703; called by muse, mutect2, varscan2
- PDE4D | c.455+189543G>C | Intron (SNP) | VAF 51/120 reads (43%) | catalogued as rs1292741945, COSV58968319, COSV58980289; called by muse, varscan2
- SSPOP | n.10422G>T | RNA (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
